MMRF case MMRF_1750 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/69b4cb06-61d8-4976-91d3-5816ef6422bf

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.2 years (25,268 days); ISS stage: I; Days to last known disease status: 1,147 days (3.1 years); Days to last follow up: 1,147 days (3.1 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 51 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 51 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 128 days; Days to treatment end: 128 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -22 (ECOG 1): M Protein 2.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.34 mg/dL; Immunoglobulin G 3.24 g/L; Immunoglobulin A 39.9 g/L; Immunoglobulin M 0.5 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 9 g/dL; Glucose 5.06 mmol/L; C-Reactive Protein 0.01 mg/dL.
- Day 51 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 8.03 mmol/L.
- Day 148 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Immunoglobulin G 3.91 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 3.52 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 7.21 mmol/L.
- Day 239 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.67 mg/dL; Immunoglobulin G 4.46 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 47 g/L; Total Protein 6.9 g/dL; Glucose 5.23 mmol/L.
- Day 365 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.96 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.63 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 5.83 mmol/L.
- Day 527 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Immunoglobulin G 10 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 48.6 µmol/L.
- Day 611 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 45 g/L; Total Protein 7.1 g/dL; Glucose 5.28 mmol/L.
- Day 695 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.68 g/L; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 5.56 mmol/L.
- Day 785 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.62 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.15 mmol/L; Albumin 46 g/L; Total Protein 7.3 g/dL; Glucose 6.6 mmol/L.
- Day 891 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 0.11 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.72 g/L; Beta 2 Microglobulin 1.8 µg/mL; Hemoglobin 6.88 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 5.17 mmol/L.
- Day 958 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.57 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.79 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 44 g/L; Total Protein 7.5 g/dL; Glucose 6.33 mmol/L.
- Day 1,024 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 0.96 g/L; Immunoglobulin M 0.69 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 4.95 mmol/L.
- Day 1,147 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 1.02 g/L; Immunoglobulin M 0.71 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.5 g/dL; Glucose 6.99 mmol/L.

Other clinical attributes
- Day -22: Weight: 81 kg; Height: 173 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1750_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -22 days.
- Sample MMRF_1750_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -22 days.
